Somatic mutation profile of tumor specimen MP2PRT-PAVAYT-TMP1-A (aliquot MP2PRT-PAVAYT-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVAYT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (633 days).
Specimen MP2PRT-PAVAYT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 389b36eb-ad9c-40bd-8d9d-eca9010c1ce5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAYT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAYT-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e9c056d-6c0c-4187-bfe0-0f3462ac89c4

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as rs397507540, CM053389, CM067454, COSV61004831; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP3B2 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs868273372, COSV55608398; called by muse, mutect2, varscan2
- FAM166C | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs775521325; called by muse, mutect2, varscan2
- PLXNA1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs757660956, COSV52527822; called by muse, mutect2, varscan2
- RELN | c.4399G>A p.G1467S | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs1251127779, COSV58986829; called by muse, mutect2, varscan2
- SEMA6D | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs758696033, COSV60374717, COSV60376077; called by muse, mutect2
- DST | c.5264A>T p.N1755I | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CSMD2 | c.2640G>A p.G880= | Silent (SNP) | VAF 129/301 reads (43%) | called by muse, mutect2, varscan2
- DHX58 | c.357C>T p.H119= | Silent (SNP) | VAF 87/342 reads (25%) | catalogued as rs781972471; called by muse, mutect2, varscan2
- DYTN | c.258G>A p.P86= | Silent (SNP) | VAF 56/201 reads (28%) | catalogued as rs747863949, COSV101510795; called by muse, mutect2, varscan2
- LRFN2 | c.390C>T p.I130= | Silent (SNP) | VAF 95/392 reads (24%) | catalogued as COSV57827700, COSV57829989; called by muse, mutect2, varscan2
- MARCHF7 | c.729T>C p.S243= | Silent (SNP) | VAF 99/208 reads (48%) | called by muse, mutect2, varscan2
- SLC13A2 | c.1443G>A p.T481= | Silent (SNP) | VAF 69/325 reads (21%) | catalogued as rs200870258; called by muse, mutect2, varscan2
- ZSCAN2 | c.*602C>T | 3'UTR (SNP) | VAF 124/274 reads (45%) | called by muse, mutect2, varscan2
